Somatic mutation profile of tumor specimen TCGA-BP-4770-01A (aliquot TCGA-BP-4770-01A-01D-1501-10) from TCGA case TCGA-BP-4770, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 73.4 years (26,824 days).
Specimen TCGA-BP-4770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 082b1b4c-063f-4b85-b9d1-0c76207a1d5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4770-11A (Solid Tissue Normal), aliquot TCGA-BP-4770-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cd73456-ca62-407a-90ae-dd2ad3dc6054

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 12, Splice Site 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 80/114 reads (70%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ALDH16A1 | c.2165T>A p.V722E | Missense Mutation (SNP) | VAF 119/182 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53193596; called by muse, mutect2, varscan2
- ARMH4 | c.1832A>G p.E611G | Missense Mutation (SNP) | VAF 136/483 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV50763272; called by muse, mutect2, varscan2
- C5 | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 83/443 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV56326067, COSV56326209; called by muse, mutect2, varscan2
- CD180 | c.1732C>A p.P578T | Missense Mutation (SNP) | VAF 109/205 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV56517571; called by muse, mutect2, varscan2
- CYP4F2 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as rs752587468, COSV55617393; called by muse, mutect2, varscan2
- DMRT2 | c.1102C>G p.Q368E | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV52401574; called by muse, mutect2, varscan2
- DYSF | c.347C>G p.S116W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV50266771, COSV50293948; called by muse, mutect2, varscan2
- FAM110C | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.77); PolyPhen benign (0.178); catalogued as COSV59655882, COSV59656735; called by muse, mutect2, varscan2
- FREM1 | c.5596C>A p.H1866N | Missense Mutation (SNP) | VAF 102/374 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV66521784; called by muse, mutect2, varscan2
- GPR15 | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 113/141 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as COSV52520387; called by muse, mutect2, varscan2
- GRIN2B | c.1947C>A p.N649K | Missense Mutation (SNP) | VAF 145/350 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74205532; called by muse, mutect2, varscan2
- IFNL3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 69/103 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV69829893; called by muse, mutect2, varscan2
- KLHL7 | c.1201G>A p.E401K (on ENST00000339077 / NM_001031710.3; = p.E353K on NM_018846.5) | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1440770028, COSV59160880, COSV59163270; called by muse, mutect2, varscan2
- MAGI3 | c.963G>C p.W321C | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56833329; called by muse, mutect2
- MTUS2 | c.3405A>T p.E1135D (on ENST00000612955 / NM_001366650.1; = p.E114D on NM_015233.6) | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV60158049; called by muse, mutect2, varscan2
- NCF1 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368948045, COSV56876177; called by muse, mutect2, varscan2
- OR10G7 | c.77T>A p.F26Y | Missense Mutation (SNP) | VAF 117/153 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs1172589432, COSV57866668; called by muse, mutect2, varscan2
- OR1S1 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 197/872 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV58706742; called by muse, mutect2, varscan2
- OR2AG1 | c.121A>G p.S41G | Missense Mutation (SNP) | VAF 115/384 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV56625818; called by muse, mutect2, varscan2
- PCDHA10 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV56493040; called by muse, mutect2, varscan2
- PCDHGB7 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV53928923; called by muse, mutect2, varscan2
- PDE8A | c.1511A>T p.E504V | Missense Mutation (SNP) | VAF 176/235 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV59636296; called by muse, mutect2, varscan2
- PLEC | c.11957C>A p.P3986Q (on ENST00000322810 / NM_201380.4; = p.P3876Q on NM_000445.5) | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59624875; called by muse, mutect2, varscan2
- RAB6B | c.345G>C p.R115S | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV53313005; called by muse, mutect2
- RB1 | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs483352690, CM034902, CM045967, CS050405, CS081965, CS083261, COSV57303318, COSV57309017, COSV57322012; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RELN | c.7018G>C p.G2340R | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58996199; called by muse, mutect2
- RGS6 | c.995G>T p.R332I | Missense Mutation (SNP) | VAF 126/337 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV59572648; called by muse, varscan2
- RPGRIP1 | c.2011G>T p.G671W | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52848168, COSV52857321; called by muse, mutect2
- SERPINB13 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 111/256 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs139825462; called by muse, mutect2, varscan2
- SLC12A9 | c.1864A>C p.M622L | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV51932537, COSV51935231; called by muse, mutect2, varscan2
- SMARCAL1 | c.863-2A>T p.X288_splice | Splice Site (SNP) | VAF 89/131 reads (68%) | catalogued as CS020335, COSV61920652; called by muse, mutect2, varscan2
- SPEM1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs527349281, COSV100080756, COSV57209793; called by muse, mutect2, varscan2
- SRBD1 | c.2675C>A p.P892H | Missense Mutation (SNP) | VAF 186/683 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55397814; called by muse, mutect2, varscan2
- STAR | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 71/113 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV51699232; called by muse, mutect2, varscan2
- SYNE1 | c.1016T>C p.M339T (on ENST00000367255 / NM_182961.4; = p.M346T on NM_033071.3) | Missense Mutation (SNP) | VAF 486/987 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs1489130675, COSV54956052; called by muse, mutect2, varscan2
- TASOR2 | c.6984A>T p.E2328D | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as rs202125233; called by muse, mutect2, varscan2
- TEKT5 | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs145065368; called by muse, mutect2, varscan2
- TIMM17B | c.193A>G p.S65G | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV54430085; called by muse, mutect2, varscan2
- ULK3 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 235/311 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51510892; called by muse, mutect2, varscan2
- UNC79 | c.3637A>G p.R1213G (on ENST00000393151 / NM_001346218.2; = p.R1036G on NM_020818.5) | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56382632; called by muse, mutect2
- ZNF99 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV68055449; called by muse, mutect2, varscan2
- ARFGEF2 | c.2367_2392del p.K789Nfs*2 | Frame Shift Del (DEL) | VAF 62/90 reads (69%) | called by pindel, varscan2*
- TRAV21 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.143); called by muse, mutect2
- DCAF1 | c.3489T>G p.L1163= | Silent (SNP) | VAF 70/242 reads (29%) | catalogued as rs782684307, COSV60042181; called by muse, mutect2, varscan2
- LRRC56 | c.735G>C p.L245= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1226647869, COSV54240033; called by muse, varscan2
- MUC16 | c.34197T>C p.D11399= | Silent (SNP) | VAF 364/589 reads (62%) | catalogued as COSV67459140; called by mutect2, varscan2
- MUC16 | c.13101A>G p.T4367= | Silent (SNP) | VAF 185/278 reads (67%) | catalogued as COSV67459147; called by muse, mutect2, varscan2
- NAALADL1 | c.717G>T p.L239= | Silent (SNP) | VAF 82/118 reads (69%) | catalogued as COSV60523492; called by muse, mutect2, varscan2
- NIFK | c.390C>T p.L130= | Silent (SNP) | VAF 134/462 reads (29%) | catalogued as COSV53534597; called by muse, mutect2, varscan2
- OR2T4 | c.852T>C p.Y284= | Silent (SNP) | VAF 42/238 reads (18%) | catalogued as rs138844789; called by muse, mutect2, varscan2
- OR4A5 | c.57T>A p.P19= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV60522187; called by muse, mutect2, varscan2
- OR8H1 | c.921A>G p.R307= | Silent (SNP) | VAF 24/206 reads (12%) | catalogued as rs774300048, COSV57293682; called by mutect2, varscan2
- TNR | c.3282T>A p.I1094= | Silent (SNP) | VAF 225/297 reads (76%) | catalogued as COSV54880166; called by muse, mutect2, varscan2
- UNC13D | c.2175G>A p.E725= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV52884015; called by muse, mutect2, varscan2
- ZNF141 | c.849C>T p.I283= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV53657959; called by muse, mutect2
- AL162726.3 | n.255+83144G>A | Intron (SNP) | VAF 14/378 reads (4%) | catalogued as rs1294530458; called by muse, mutect2
